Gene-level copy-number profile of tumor specimen ALCH-B2U1-TTP1-A from ALCHEMIST case ALCH-B2U1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,897 days).
Specimen ALCH-B2U1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fe6c25a-0227-4aac-9691-990545cc730b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2U1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/77c700e2-a8c0-41da-b85c-725eb4bf5391

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 2,123; copy number 2: 52,291; copy number 3: 2,858; copy number 4: 177; copy number 5: 764; copy number 6: 10; copy number 7: 14; copy number 8: 6; copy number 9: 6; copy number 10: 8; copy number 11: 4; copy number 12: 3; copy number 14: 7; copy number 16: 3; copy number 17: 1; copy number 19: 2; copy number 21: 1; copy number 26: 1; copy number 30: 3; copy number 51: 2; copy number 70: 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,214,153, 1 gene: TNFRSF4.
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr1:1,378,666–1,379,032, 1 gene: NDUFB4P8.
- chr1:3,560,695–3,560,790, 1 gene (within-gene range 0–3): MIR551A.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr2:91,617,160–91,685,884, 3 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1.
- chr2:91,859,384–91,859,481, 1 gene: AC127391.1.
- chr3:75,421,552–75,435,110, 1 gene (within-gene range 0–1): FAM86DP.
- chr3:130,089,433–130,094,304, 1 gene (within-gene range 0–2): LINC02014.
- chr4:164,915,565–165,060,554, 19 genes: TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P.
- chr7:101,195,007–101,201,038, 1 gene: MOGAT3.
- chr7:101,269,938–101,273,715, 2 genes: RNU6-1104P, AC006329.1.
- chr8:11,761,256–11,763,223, 1 gene: C8orf49.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,642,383–61,642,494, 1 gene: Y_RNA.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:136,791,344–136,810,042, 4 genes (within-gene range 0–4): TMEM141, AL355987.3, CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–4): CCDC183-AS1.
- chr10:21,452,197–21,497,260, 5 genes: AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915.
- chr11:8,224,309–8,268,716, 1 gene: LMO1.
- chr11:12,261,426–12,263,173, 1 gene (within-gene range 0–2): AC079329.1.
- chr14:105,597,691–105,601,728, 1 gene (within-gene range 0–9): IGHE.
- chr16:89,873,570–89,918,233, 2 genes (within-gene range 0–3): TCF25, AC092143.3.
- chr17:1,181,893–1,185,086, 1 gene (within-gene range 0–1): AC016292.1.
- chr17:7,288,263–7,294,639, 1 gene: YBX2.
- chr17:7,330,452–7,351,477, 2 genes: AC026954.1, ACAP1.
- chr17:7,389,734–7,404,097, 2 genes (within-gene range 0–2): TMEM256-PLSCR3, TMEM256.
- chr20:36,870,099–36,870,402, 1 gene: RN7SL156P.
- chr21:10,122,273–10,129,029, 1 gene: CR382287.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 836 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,167,104–1,179,555, 5 genes, copy number 10–19 (within-gene range 3–19): MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1.
- chr1:1,216,909–1,232,067, 1 gene, copy number 6: SDF4.
- chr1:1,280,436–1,309,609, 3 genes, copy number 30 (within-gene range 4–30): SCNN1D, ACAP3, MIR6726.
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr8:142,700,111–142,727,016, 2 genes, copy number 5: LY6K, LNCOC1.
- chr8:142,740,949–142,812,120, 9 genes, copy number 5–10: SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4.
- chr8:143,566,192–143,578,649, 3 genes, copy number 9–26 (within-gene range 1–26): MROH6, AC067930.4, NAPRT.
- chr8:144,049,079–144,063,965, 3 genes, copy number 11–17: SMPD5, OPLAH, MIR6846.
- chr9:136,712,572–136,726,239, 3 genes, copy number 7–11: DIPK1B, SNORA17B, SNORA17B.
- chr9:136,738,167–136,766,255, 6 genes, copy number 6–16: LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15.
- chr11:565,660–568,457, 2 genes, copy number 5: MIR210HG, MIR210.
- chr11:612,553–627,181, 3 genes, copy number 14: IRF7, CDHR5, SCT.
- chr14:104,681,146–104,722,535, 2 genes, copy number 5–7 (within-gene range 2–7): INF2, AL583722.3.
- chr14:104,800,596–104,804,712, 1 gene, copy number 5: ZBTB42.
- chr14:104,857,792–104,858,836, 1 gene, copy number 6: AL583810.1.
- chr14:105,489,855–105,499,575, 1 gene, copy number 11 (within-gene range 3–11): TEDC1.
- chr14:105,620,506–105,626,066, 1 gene, copy number 12 (within-gene range 3–12): IGHG4.
- chr14:105,647,924–105,669,843, 2 genes, copy number 5–7 (within-gene range 2–7): COPDA1, IGHGP.
- chr16:560,394–584,109, 4 genes, copy number 7–8: PRR35, PIGQ, NHLRC4, Z98883.1.
- chr16:629,239–768,865, 23 genes, copy number 5–51 (within-gene range 3–51): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN.
- chr16:769,428–783,370, 1 gene, copy number 5 (within-gene range 1–5): MSLNL.
- chr16:784,974–981,318, 6 genes, copy number 5–6 (within-gene range 4–6): RPUSD1, CHTF18, GNG13, AL023882.1, AL031008.1, LMF1.
- chr16:898,967–1,225,257, 19 genes, copy number 5–12: AL008727.1, LMF1-AS1, AC009041.3, CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10.
- chr16:1,256,059–1,280,544, 5 genes, copy number 6–9: TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5.
- chr16:1,305,547–1,309,413, 1 gene, copy number 9 (within-gene range 3–9): AC120498.9.
- chr16:88,863,333–88,866,660, 1 gene, copy number 21: PABPN1L.
- chr19:859,664–863,641, 1 gene, copy number 70: CFD.
- chr19:917,287–921,005, 1 gene, copy number 8: KISS1R.
- chr19:984,332–1,174,268, 13 genes, copy number 5–8: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2.
- chr19:1,238,179–1,239,522, 1 gene, copy number 9: AC004221.1.
- chr19:1,259,384–1,279,244, 3 genes, copy number 7–8: CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,383,527–1,435,687, 5 genes, copy number 5–7 (within-gene range 3–7): NDUFS7, AC005329.3, AC005329.1, GAMT, DAZAP1.
- chr19:1,461,143–1,513,604, 4 genes, copy number 5–7: C19orf25, PCSK4, REEP6, ADAMTSL5.
- chr19:1,508,375–1,508,963, 1 gene, copy number 7: AC027307.1.
- chr19:1,876,810–1,885,496, 1 gene, copy number 5: ABHD17A.
- chr20:62,307,955–62,367,312, 3 genes, copy number 5 (within-gene range 2–22): LAMA5, MIR4758, LAMA5-AS1.
- chr20:62,387,103–62,407,285, 2 genes, copy number 7 (within-gene range 3–7): RPS21, CABLES2.
- chr20:62,575,590–62,603,355, 2 genes, copy number 5–8: BX640514.1, BX640514.2.
- chr20:62,796,473–62,861,822, 6 genes, copy number 5: MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1.
- chr20:63,166,797–63,180,903, 2 genes, copy number 14: AL096828.1, MIR124-3.

Autosomal genes at a single copy (total copy number 1): 2,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
